Somatic mutation profile of tumor specimen TCGA-06-0171-02A (aliquot TCGA-06-0171-02A-11D-2280-08) from TCGA case TCGA-06-0171, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-06-0171-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39d853e5-70b5-4266-93c0-94c9ce73a68e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0171-10A (Blood Derived Normal), aliquot TCGA-06-0171-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af29cb03-921e-40ff-a81b-55f0a0d25ac5

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4531A>G p.T1511A | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51840388; called by muse, mutect2, varscan2
- COL6A3 | c.7475C>T p.S2492L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754480145, COSV55079530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2
- CYP4F11 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201156268, COSV56125672; called by muse, mutect2
- HLTF | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | catalogued as COSV59498743; called by muse, mutect2, varscan2
- LILRB4 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54403569; called by muse, mutect2, varscan2
- MAMDC4 | c.2526G>A p.W842* (on ENST00000445819; = p.W763* on NM_206920.3) | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV56374952; called by muse, mutect2, varscan2
- MDC1 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 36/539 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV64523133; called by muse, mutect2
- MTHFR | c.1928del p.L643Pfs*19 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as COSV57171285; called by mutect2, pindel, varscan2
- ONECUT2 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs769761027, COSV72152960; called by muse, mutect2
- PKHD1 | c.5965C>T p.L1989F | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61860124; called by muse, mutect2
- POTED | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV55046523; called by muse, mutect2
- PPP3R2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569559919, COSV62450543; called by muse, mutect2
- PXK | c.1181+1G>A p.X394_splice | Splice Site (SNP) | VAF 4/49 reads (8%) | catalogued as rs1213871054, COSV57086762; called by muse, mutect2
- RBM47 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs776189003, COSV55930008; called by muse, mutect2
- RBPJL | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.564); catalogued as COSV59212775; called by muse, mutect2, varscan2
- RIMS2 | c.2960G>A p.R987H (on ENST00000666250 / NM_001348490.2; = p.R795H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV51655098; called by muse, mutect2
- RNF168 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58836695; called by muse, mutect2
- RPTOR | c.3940-2A>G p.X1314_splice | Splice Site (SNP) | VAF 12/126 reads (10%) | catalogued as COSV60803038; called by muse, mutect2
- SLC4A7 | c.3622G>A p.V1208M | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs200768562, COSV55394801; called by muse, mutect2
- TCF21 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs775850686, COSV52817660; called by muse, varscan2
- TRIM24 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs770786278, COSV58968920; called by muse, mutect2, varscan2
- TRIML2 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 37/498 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV58714539; called by muse, mutect2
- TRPV6 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63890447; called by muse, mutect2, varscan2
- ZNF407 | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs546961134, COSV55242402; called by muse, mutect2, varscan2
- CFAP65 | c.4782_4784del p.P1595del | In Frame Del (DEL) | VAF 16/182 reads (9%) | called by mutect2, pindel
- IGHV3-43 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.11970T>C p.S3990= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV54203522; called by muse, mutect2, varscan2
- EP400 | c.3148T>C p.L1050= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- FAM98A | c.498A>G p.Q166= | Silent (SNP) | VAF 16/249 reads (6%) | catalogued as rs561820764, COSV53208861; called by muse, mutect2
- INPP5K | c.54C>T p.V18= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs752181436, COSV57439847, COSV57441312; called by muse, mutect2
- KRTAP13-1 | c.429C>T p.G143= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs565845316, COSV62662638; called by mutect2, varscan2
- SAMD3 | c.597C>T p.D199= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs768298745, COSV60774019, COSV60776122; called by muse, mutect2
- ZNF98 | c.666C>G p.A222= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV63334322, COSV63336247; called by muse, mutect2
- WNK2 | c.*17C>T | 3'UTR (SNP) | VAF 10/124 reads (8%) | catalogued as rs372704041; called by muse, mutect2
